Somatic mutation profile of tumor specimen TCGA-D3-A1Q1-06A (aliquot TCGA-D3-A1Q1-06A-21D-A196-08) from TCGA case TCGA-D3-A1Q1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.0 years (29,215 days).
Specimen TCGA-D3-A1Q1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb668634-9670-4c4e-bb13-b855e5540a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q1-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q1-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40e9d5f1-355d-4b88-aecc-f76391942fb2

The open-access MAF lists 52 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 119/158 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54637281; called by muse, mutect2, varscan2
- AP4B1 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56725645; called by muse, mutect2, varscan2
- ARMC3 | c.2506G>A p.G836R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53063550; called by muse, mutect2, varscan2
- CDK5 | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as COSV52521271, COSV52523651; called by muse, mutect2, varscan2
- CFLAR | c.355T>G p.Y119D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV57937662; called by muse, mutect2, varscan2
- CHPF | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs142415191, COSV60534550, COSV60535493; called by muse, mutect2, varscan2
- DEF6 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57353228; called by muse, mutect2, varscan2
- DYNC2H1 | c.1768T>C p.S590P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV62098197; called by muse, mutect2, varscan2
- FANCD2 | c.591G>C p.M197I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV55041058; called by muse, mutect2, varscan2
- GPRIN1 | c.2089G>C p.A697P | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs946371447, COSV56140986; called by muse, varscan2
- HIGD1C | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 58/299 reads (19%) | catalogued as COSV68250722; called by muse, mutect2, varscan2
- ITPR3 | c.2881G>T p.D961Y | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.377); catalogued as COSV65411414; called by muse, mutect2, varscan2
- KCNS2 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs149723156; called by muse, varscan2
- MARCHF7 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52029520; called by muse, mutect2, varscan2
- MEI1 | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV55904453; called by muse, mutect2, varscan2
- MITD1 | c.723T>A p.F241L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV56806554; called by muse, mutect2, varscan2
- MT2A | c.97T>C p.C33R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55330075; called by muse, mutect2, varscan2
- NME8 | c.1172A>G p.D391G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV52252063; called by muse, varscan2
- NOX5 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1264697147, COSV52991251; called by mutect2, varscan2
- PCDHGA3 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs757266874, COSV53976111; called by muse, mutect2, varscan2
- RNF2 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62279708; called by muse, varscan2
- SAMD9L | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV100560768, COSV59082822; called by muse, mutect2, varscan2
- SLC6A7 | c.863G>C p.W288S | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV57939090; called by muse, mutect2, varscan2
- SMC1A | c.1145C>G p.A382G | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59130027; called by muse, mutect2, varscan2
- ST18 | c.1272C>A p.N424K | Missense Mutation (SNP) | VAF 63/546 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52499141; called by muse, mutect2, varscan2
- SULF2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs142401598; called by mutect2, varscan2
- TECTA | c.4924G>A p.V1642I | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV50732924; called by muse, mutect2, varscan2
- TRIM28 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53400896; called by muse, mutect2, varscan2
- TRIM9 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV53619559; called by muse, mutect2
- TTN | c.43628G>C p.G14543A (on ENST00000591111; = p.G7119A on NM_003319.4) | Missense Mutation (SNP) | VAF 125/246 reads (51%) | PolyPhen probably damaging (0.999); catalogued as COSV60158382; called by muse, mutect2, varscan2
- TTPAL | c.640-2A>G p.X214_splice | Splice Site (SNP) | VAF 28/84 reads (33%) | catalogued as COSV52829223; called by muse, varscan2
- UBE2M | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as rs1198239092, COSV53397232; called by mutect2, varscan2
- ZFHX4 | c.8666C>G p.T2889R | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.563); catalogued as rs1426111113, COSV51455691; called by muse, mutect2
- ZNF2 | c.316T>A p.W106R (on ENST00000611147 / NM_001291605.2; = p.W93R on NM_021088.4) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54637416; called by muse, mutect2, varscan2
- ZNF669 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 137/147 reads (93%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs375976348; called by muse, mutect2, varscan2
- ZNF777 | c.2424C>A p.C808* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV56098621; called by muse, mutect2, varscan2
- ARHGEF35 | c.666G>T p.L222F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by mutect2, varscan2
- COL11A2 | c.1583C>T p.T528I (on ENST00000341947 / NM_080680.3; = p.T421I on NM_080679.2) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); called by mutect2, varscan2
- LRRC37A2 | c.3683del p.G1228Efs*21 | Frame Shift Del (DEL) | VAF 18/193 reads (9%) | called by mutect2, pindel, varscan2
- TNR | c.3361A>G p.T1121A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2
- UNC13D | c.307del p.V103Sfs*11 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- CDCA3 | c.519G>A p.R173= | Silent (SNP) | VAF 54/399 reads (14%) | catalogued as COSV57529248; called by muse, mutect2, varscan2
- EPC2 | c.1248T>G p.A416= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV51546150; called by muse, mutect2, varscan2
- GDF3 | c.141G>A p.V47= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV61712936; called by mutect2, varscan2
- LYG2 | c.303C>A p.I101= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV60715968; called by muse, mutect2, varscan2
- MAFB | c.207G>A p.S69= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV64826795; called by muse, mutect2, varscan2
- PCDHB16 | c.2307G>A p.P769= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV53361401; called by muse, mutect2, varscan2
- SLC45A3 | c.813G>C p.L271= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV65655120; called by muse, mutect2, varscan2
- SLC6A5 | c.867G>T p.V289= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as COSV54228611; called by muse, mutect2, varscan2
- SNED1 | c.3603C>T p.G1201= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs369849516; called by mutect2, varscan2
- TASOR2 | c.2955C>T p.G985= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV60168230; called by mutect2, varscan2
